Somatic mutation profile of tumor specimen 0DH9LT from CCDI case PBBUGE, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Alveolar rhabdomyosarcoma; Tissue or organ of origin: Pelvis, NOS; Age at diagnosis: 16.4 years (5,975 days).
Specimen 0DH9LT: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c983275a-f43e-4f48-b633-82c31ddbf077.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DH9KZ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/801f762b-8b08-4397-914b-950ca843dc03

The open-access MAF lists 40 somatic variants for this specimen: 25 protein-altering or splice-affecting, 11 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 11, Frame Shift Del 3, Intron 3, Nonsense Mutation 2, Frame Shift Ins 1, Splice Region 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CLIP2 | c.671G>A p.R224H | Missense Mutation (SNP) | VAF 106/350 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs782782032; called by muse, mutect2, varscan2
- CYTIP | c.476C>T p.T159M | Missense Mutation (SNP) | VAF 67/515 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.073); catalogued as rs534886532; called by muse, mutect2, varscan2
- DOCK2 | c.2059C>T p.R687W | Missense Mutation (SNP) | VAF 279/441 reads (63%) | SIFT deleterious (0.04); PolyPhen benign (0.086); catalogued as rs993592703, COSV56978796; called by muse, mutect2, varscan2
- ENPP3 | c.2345T>C p.V782A | Missense Mutation (SNP) | VAF 110/381 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.395); catalogued as rs1353385838; called by muse, mutect2, varscan2
- KLHDC7B | c.1528C>T p.R510C (on ENST00000395676; = p.R1151C on NM_138433.5) | Missense Mutation (SNP) | VAF 133/437 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs750273973, COSV67464640; called by muse, mutect2, varscan2
- NOX5 | c.190C>T p.R64* | Nonsense Mutation (SNP) | VAF 85/401 reads (21%) | catalogued as rs767133281; called by muse, mutect2, varscan2
- NPY1R | c.776A>G p.K259R | Missense Mutation (SNP) | VAF 171/313 reads (55%) | SIFT tolerated (0.44); PolyPhen benign (0.127); catalogued as rs953772005; called by muse, mutect2, varscan2
- PCDH1 | c.349C>T p.R117C | Missense Mutation (SNP) | VAF 193/314 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1288264074; called by muse, mutect2, varscan2
- SELP | c.790C>A p.P264T | Missense Mutation (SNP) | VAF 105/446 reads (24%) | SIFT tolerated (0.54); PolyPhen benign (0.419); catalogued as rs143090272; called by muse, mutect2, varscan2
- SH3RF3 | c.863C>T p.T288M | Missense Mutation (SNP) | VAF 95/243 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs373446779; called by muse, mutect2, varscan2
- SLC39A6 | c.221G>A p.G74E | Missense Mutation (SNP) | VAF 80/347 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs751468136; called by muse, mutect2, varscan2
- TCHHL1 | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 86/544 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.036); catalogued as COSV64286000; called by muse, mutect2, varscan2
- AMPD2 | c.737del p.P246Lfs*63 | Frame Shift Del (DEL) | VAF 112/530 reads (21%) | called by mutect2, varscan2
- GATA2 | c.241G>T p.G81* | Nonsense Mutation (SNP) | VAF 107/772 reads (14%) | called by muse, mutect2, varscan2
- HUS1 | c.34T>C p.C12R | Missense Mutation (SNP) | VAF 77/412 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.352); called by muse, mutect2, varscan2
- MACROD2 | c.1157A>T p.N386I (on ENST00000642719; = p.N358I on NM_080676.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/660 reads (3%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2
- PAK1IP1 | c.246T>C p.S82= | Splice Region (SNP) | VAF 124/281 reads (44%) | called by muse, varscan2
- PCDH15 | c.2659G>C p.D887H | Missense Mutation (SNP) | VAF 56/312 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.866); called by muse, mutect2
- PLEKHD1 | c.301T>C p.Y101H | Missense Mutation (SNP) | VAF 16/356 reads (4%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.796); called by muse, mutect2
- PRDM2 | c.507dup p.K170Efs*10 | Frame Shift Ins (INS) | VAF 75/328 reads (23%) | called by mutect2, varscan2
- PTTG2 | c.349T>C p.F117L | Missense Mutation (SNP) | VAF 22/639 reads (3%) | SIFT tolerated (0.52); PolyPhen benign (0.088); called by muse, mutect2
- RRP7A | c.635_659del p.R212Qfs*35 | Frame Shift Del (DEL) | VAF 62/345 reads (18%) | called by mutect2, varscan2
- SLC16A11 | c.494C>T p.A165V (on ENST00000308009; = p.A141V on NM_153357.3) | Missense Mutation (SNP) | VAF 58/549 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.868); called by muse, mutect2, varscan2
- TNFSF15 | c.292C>A p.H98N | Missense Mutation (SNP) | VAF 25/238 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF609 | c.1263del p.P422Lfs*29 | Frame Shift Del (DEL) | VAF 40/153 reads (26%) | called by mutect2, varscan2
- DNAJC5G | c.81C>T p.G27= | Silent (SNP) | VAF 246/582 reads (42%) | catalogued as rs755635652, COSV56079563, COSV99940509; called by muse, varscan2
- GGT1 | c.690C>T p.N230= | Silent (SNP) | VAF 114/623 reads (18%) | catalogued as rs375316441; called by muse, mutect2, varscan2
- GRPR | c.1014C>G p.L338= | Silent (SNP) | VAF 222/518 reads (43%) | catalogued as COSV66669921; called by muse, mutect2, varscan2
- HMGB3 | c.357T>C p.S119= | Silent (SNP) | VAF 28/522 reads (5%) | catalogued as rs1557425256; called by muse, mutect2
- KDM4C | c.189C>T p.D63= | Silent (SNP) | VAF 11/282 reads (4%) | called by muse, mutect2
- KNTC1 | c.921A>T p.S307= | Silent (SNP) | VAF 157/273 reads (58%) | catalogued as rs1240066075; called by muse, mutect2, varscan2
- MAP7 | c.1689C>T p.R563= | Silent (SNP) | VAF 39/284 reads (14%) | catalogued as rs371285959; called by muse, mutect2, varscan2
- NDST2 | c.1461C>A p.L487= | Silent (SNP) | VAF 170/440 reads (39%) | called by muse, mutect2, varscan2
- PCDH15 | c.2661C>T p.D887= | Silent (SNP) | VAF 56/321 reads (17%) | catalogued as COSV100214941; called by muse, mutect2
- SHANK3 | c.669C>T p.S223= | Silent (SNP) | VAF 304/517 reads (59%) | catalogued as rs372139101; called by muse, mutect2, varscan2
- SPP2 | c.357C>G p.T119= | Silent (SNP) | VAF 33/251 reads (13%) | called by muse, mutect2, varscan2
- KCNG1 | c.775-57C>T | Intron (SNP) | VAF 108/209 reads (52%) | catalogued as rs917312735; called by muse, varscan2
- MED9 | c.*64A>T | 3'UTR (SNP) | VAF 30/118 reads (25%) | called by muse, mutect2, varscan2
- PHYHIP | c.458+9G>A | Intron (SNP) | VAF 174/336 reads (52%) | catalogued as rs374033352; called by muse, varscan2
- TMC2 | c.83-77G>A | Intron (SNP) | VAF 8/196 reads (4%) | called by muse, mutect2
